Gene-level copy-number profile of tumor specimen TCGA-50-6595-01A from TCGA case TCGA-50-6595, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 74.5 years (27,197 days).
Specimen TCGA-50-6595-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.01fc2bf2-7103-4ff8-817d-8d16192c1e04.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-50-6595-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ecca4e4c-70fe-416a-94cc-fe20dd963284

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,065; copy number 2: 43,472; copy number 3: 11,233; copy number 4: 1,473; copy number 5: 1,107; copy number 6: 146; copy number 9: 207; copy number 11: 112.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-50-6595-01A-12D-1854-01): tumor purity 0.22, ploidy 2.43, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,572 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:70,972–63,176,019, 1,086 genes, copy number 5 (broad region; genes not listed).
- chr8:150,584–8,059,674, 190 genes, copy number 6–9 (broad region; genes not listed).
- chr8:8,065,599–8,089,089, 3 genes, copy number 9: AC105233.5, AC105233.2, MIR548I3.
- chr8:8,414,204–12,115,516, 114 genes, copy number 5–9 (broad region; genes not listed).
- chr8:12,128,107–12,129,298, 1 gene, copy number 9: AC130366.1.
- chr8:38,901,235–43,674,591, 112 genes, copy number 11 (within-gene range 1–11) (broad region; genes not listed).
- chr14:56,303,490–59,870,776, 66 genes, copy number 6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,065. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
